Somatic mutation profile of tumor specimen TCGA-23-1116-01A (aliquot TCGA-23-1116-01A-01W-0486-08) from TCGA case TCGA-23-1116, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 83.4 years (30,464 days).
Specimen TCGA-23-1116-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ae38bcd6-d792-42d5-a9e3-dfac382cf737.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-23-1116-10A (Blood Derived Normal), aliquot TCGA-23-1116-10A-01W-0486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c13c893-d076-4781-834d-2d42076826c1

The open-access MAF lists 122 somatic variants for this specimen: 90 protein-altering or splice-affecting, 28 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 79, Silent 28, Nonsense Mutation 6, Intron 3, Splice Site 2, Frame Shift Ins 1, Frame Shift Del 1, 3'Flank 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.783-1_792del p.X261_splice | Splice Site (DEL) | VAF 24/107 reads (22%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- AC093525.2 | c.1099G>A p.G367S | Missense Mutation (SNP) | VAF 232/290 reads (80%) | PolyPhen benign (0.103); catalogued as rs1413615299, COSV99566029, COSV99566108; called by muse, mutect2
- ADAM9 | c.1217C>A p.P406Q | Missense Mutation (SNP) | VAF 4/86 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101166246, COSV65959042; called by muse, mutect2
- ADCY6 | c.3500G>A p.S1167N | Missense Mutation (SNP) | VAF 16/203 reads (8%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV100326872; called by muse, mutect2
- ADGRG4 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 36/420 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99796524; called by muse, mutect2
- AMPH | c.404T>A p.I135N | Missense Mutation (SNP) | VAF 15/238 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100343428; called by muse, mutect2
- ANGPT2 | c.685G>T p.E229* | Nonsense Mutation (SNP) | VAF 24/248 reads (10%) | catalogued as COSV100291164; called by muse, mutect2
- ARMCX5-GPRASP2 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 28/342 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs747805882, COSV63437124; called by muse, mutect2
- ATAD3A | c.1382C>T p.A461V | Missense Mutation (SNP) | VAF 155/1155 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs554255312; called by mutect2, varscan2
- BFSP1 | c.625G>T p.E209* | Nonsense Mutation (SNP) | VAF 14/241 reads (6%) | catalogued as COSV100925449; called by muse, mutect2
- BNIP5 | c.1857G>T p.M619I | Missense Mutation (SNP) | VAF 54/1218 reads (4%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV101465210, COSV71325650; called by muse, mutect2
- C2CD2L | c.876G>T p.Q292H | Missense Mutation (SNP) | VAF 22/326 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.948); catalogued as COSV100371471; called by muse, mutect2
- CABS1 | c.238G>C p.D80H | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV56733220; called by muse, mutect2, varscan2
- CHCHD3 | c.244C>G p.Q82E | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.13); catalogued as COSV52771670; called by muse, mutect2, varscan2
- CHST2 | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.023); catalogued as rs1218757451, COSV100536100; called by muse, mutect2, varscan2
- CNKSR1 | c.1478G>A p.W493* (on ENST00000374253 / NM_001297647.2; = p.W486* on NM_006314.3) | Nonsense Mutation (SNP) | VAF 82/296 reads (28%) | catalogued as rs758353694, COSV100128510, COSV58792612; called by muse, varscan2
- COL22A1 | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764820251, COSV57329161; called by muse, mutect2, varscan2
- CPA1 | c.926C>T p.S309F | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99163346; called by muse, mutect2
- CPAMD8 | c.3311A>G p.N1104S (on ENST00000651564; = p.N1057S on NM_015692.5) | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.121); catalogued as rs375296622; called by muse, mutect2, varscan2
- CRACD | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.599); catalogued as COSV99949920; called by muse, mutect2
- DDX1 | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.523); catalogued as COSV51838732; called by muse, mutect2, varscan2
- DDX49 | c.846G>A p.M282I | Missense Mutation (SNP) | VAF 1081/1226 reads (88%) | SIFT tolerated (0.38); PolyPhen benign (0.135); catalogued as COSV99447823; called by muse, varscan2
- DNAH9 | c.12428A>T p.E4143V | Missense Mutation (SNP) | VAF 395/1069 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV99307774; called by muse, mutect2, varscan2
- EVPL | c.2146G>T p.D716Y | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1293667773, COSV101648798; called by muse, mutect2
- F2 | c.1118G>T p.G373V | Missense Mutation (SNP) | VAF 16/426 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100319664, COSV61314806; called by muse, mutect2
- FKBP15 | c.2725A>T p.N909Y | Missense Mutation (SNP) | VAF 40/312 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.34); catalogued as rs1419732571; called by mutect2, varscan2
- FLACC1 | c.399A>C p.Q133H | Missense Mutation (SNP) | VAF 41/378 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.161); catalogued as COSV53782766; called by muse, mutect2, varscan2
- GBA3 | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV101545560; called by muse, mutect2
- GPAA1 | c.1461C>A p.S487R | Missense Mutation (SNP) | VAF 8/145 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.11); catalogued as COSV100284194; called by muse, mutect2
- GRAMD4 | c.405-1G>T p.X135_splice | Splice Site (SNP) | VAF 10/218 reads (5%) | catalogued as COSV100730625; called by muse, mutect2
- HTRA3 | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as COSV56470204, COSV56471641; called by muse, mutect2, varscan2
- IL20RA | c.1445G>A p.W482* | Nonsense Mutation (SNP) | VAF 18/91 reads (20%) | catalogued as rs201995170, COSV57356418, COSV57357361; called by muse, varscan2
- IRS1 | c.367G>A p.G123R | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.258); catalogued as COSV100524889; called by muse, mutect2, varscan2
- ITPKC | c.1345C>G p.L449V | Missense Mutation (SNP) | VAF 683/1267 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV54573881; called by muse, mutect2, varscan2
- KCNK5 | c.669C>A p.Y223* | Nonsense Mutation (SNP) | VAF 29/374 reads (8%) | catalogued as COSV63989228, COSV63989229; called by muse, mutect2
- KPNA2 | c.419C>T p.S140F | Missense Mutation (SNP) | VAF 98/1124 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100388879; called by muse, mutect2
- LAMC1 | c.4781A>C p.K1594T | Missense Mutation (SNP) | VAF 75/413 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.053); catalogued as COSV51134969; called by muse, mutect2, varscan2
- LRIT3 | c.1244T>C p.F415S | Missense Mutation (SNP) | VAF 238/428 reads (56%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100016374; called by mutect2, varscan2
- LTBR | c.1045C>T p.H349Y | Missense Mutation (SNP) | VAF 100/700 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as COSV57438527; called by muse, mutect2, varscan2
- MAN2B1 | c.2782G>A p.G928R | Missense Mutation (SNP) | VAF 28/470 reads (6%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.557); catalogued as rs754733253, COSV55476271; called by muse, mutect2
- MC3R | c.145G>C p.G49R | Missense Mutation (SNP) | VAF 46/362 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54763308, COSV54763803; called by muse, mutect2, varscan2
- MRTO4 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 60/392 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as COSV57673355; called by muse, varscan2
- MTM1 | c.379G>T p.G127C | Missense Mutation (SNP) | VAF 21/366 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); catalogued as COSV60337394; called by muse, mutect2
- MYCBP2 | c.8535G>C p.K2845N (on ENST00000357337; = p.K2883N on NM_015057.5) | Missense Mutation (SNP) | VAF 29/782 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.06); catalogued as COSV100629050; called by muse, mutect2
- NELFB | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.098); catalogued as COSV100547018; called by muse, varscan2
- NLRP5 | c.1219G>A p.V407I | Missense Mutation (SNP) | VAF 58/168 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.148); catalogued as rs200987887; called by muse, varscan2
- NOTCH3 | c.2149C>T p.R717C | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.893); catalogued as rs144163298, CM1414856; ClinVar: uncertain significance; called by mutect2, varscan2
- OR5L2 | c.808G>A p.V270I | Missense Mutation (SNP) | VAF 36/258 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV101004359; called by muse, mutect2, varscan2
- PAPPA2 | c.2678A>G p.Y893C | Missense Mutation (SNP) | VAF 44/360 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62775204; called by muse, mutect2, varscan2
- PCDHB5 | c.1529G>A p.G510D | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs782699590, COSV50648438; called by muse, varscan2
- PIGS | c.280C>A p.L94M | Missense Mutation (SNP) | VAF 13/186 reads (7%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.926); catalogued as COSV99257219; called by muse, mutect2
- PKD1L1 | c.5720G>A p.R1907H | Missense Mutation (SNP) | VAF 55/125 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.039); catalogued as rs760659567, COSV56960930; called by muse, mutect2, varscan2
- PLCB1 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 12/296 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV62063139; called by muse, mutect2
- PPARGC1B | c.682C>A p.Q228K | Missense Mutation (SNP) | VAF 22/368 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV100495118, COSV58531687; called by muse, mutect2
- PRDM2 | c.4678G>C p.A1560P | Missense Mutation (SNP) | VAF 26/477 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.328); catalogued as COSV99342607; called by muse, mutect2
- PRMT8 | c.356G>C p.G119A | Missense Mutation (SNP) | VAF 60/686 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54213459, COSV99713663; called by muse, mutect2
- RIOX1 | c.1018dup p.H340Pfs*15 | Frame Shift Ins (INS) | VAF 8/64 reads (13%) | catalogued as rs1275295829; called by mutect2, varscan2
- RLF | c.5735G>T p.G1912V | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101035665; called by muse, mutect2
- RNASE3 | c.278G>T p.R93I | Missense Mutation (SNP) | VAF 32/787 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.085); catalogued as COSV100484284; called by muse, mutect2
- ROBO1 | c.4825T>A p.S1609T | Missense Mutation (SNP) | VAF 89/456 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.344); catalogued as COSV71392663; called by muse, mutect2, varscan2
- SAMD10 | c.532G>T p.V178L | Missense Mutation (SNP) | VAF 32/254 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV53867499; called by muse, mutect2, varscan2
- SCML4 | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 64/395 reads (16%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs756466791, COSV64634415; called by muse, mutect2, varscan2
- SDC2 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT tolerated (0.83); PolyPhen benign (0.207); catalogued as rs200028820; called by muse, mutect2, varscan2
- SIM2 | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 21/562 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.362); catalogued as rs1035614454, COSV51769069; called by muse, mutect2
- SIMC1 | c.1153C>T p.P385S (on ENST00000443967 / NM_001308196.1; = p.P404S on NM_001308195.2) | Missense Mutation (SNP) | VAF 20/527 reads (4%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV100365911; called by muse, mutect2
- SMARCA2 | c.3570C>A p.Y1190* | Nonsense Mutation (SNP) | VAF 18/190 reads (9%) | catalogued as COSV100571486; called by muse, mutect2
- TANC2 | c.3604C>T p.P1202S | Missense Mutation (SNP) | VAF 38/574 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV67335515; called by mutect2, varscan2
- TBL2 | c.498G>T p.M166I | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.026); catalogued as COSV99979728; called by muse, mutect2
- THBS3 | c.1092C>A p.S364R | Missense Mutation (SNP) | VAF 17/423 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV100857700; called by muse, mutect2
- TLR9 | c.2674C>T p.R892W | Missense Mutation (SNP) | VAF 39/243 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1325467536, CM126299, COSV62346144; called by muse, mutect2, varscan2
- TMC3 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 18/604 reads (3%) | SIFT tolerated (0.74); PolyPhen benign (0.01); catalogued as COSV100845998; called by muse, mutect2
- TULP3 | c.331G>C p.D111H | Missense Mutation (SNP) | VAF 33/399 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.416); catalogued as COSV101237606; called by muse, mutect2
- ZCWPW2 | c.137G>T p.S46I | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.31); catalogued as COSV67498079; called by muse, mutect2, varscan2
- ZFP82 | c.1250T>C p.I417T | Missense Mutation (SNP) | VAF 27/651 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as rs908269233, COSV101089295; called by muse, mutect2
- ZNF365 | c.580C>A p.L194M | Missense Mutation (SNP) | VAF 35/166 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV67925192; called by muse, mutect2, varscan2
- ZNF532 | c.1513G>T p.V505F | Missense Mutation (SNP) | VAF 26/346 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100267106, COSV60172316; called by muse, mutect2
- ZNF646 | c.4556G>A p.R1519K | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.021); catalogued as COSV99762624; called by muse, mutect2, varscan2
- ZNF774 | c.1147G>A p.G383R | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.444); catalogued as COSV100586451; called by muse, mutect2, varscan2
- ZNF774 | c.1148G>A p.G383E | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.9); catalogued as COSV100586452; called by muse, mutect2, varscan2
- ZNF79 | c.927C>G p.D309E | Missense Mutation (SNP) | VAF 39/219 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61070407; called by muse, varscan2
- ZSWIM8 | c.2653G>A p.V885M | Missense Mutation (SNP) | VAF 83/445 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as COSV67131722; called by muse, mutect2, varscan2
- AGPAT4 | c.578G>T p.R193L | Missense Mutation (SNP) | VAF 86/253 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.058); called by mutect2, varscan2
- CES3 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 28/659 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2
- EP400 | c.8657C>T p.P2886L | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- GFRA1 | c.900C>A p.N300K | Missense Mutation (SNP) | VAF 42/571 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GSTCD | c.5A>T p.K2I | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.075); called by mutect2, varscan2
- OR2T34 | c.270G>C p.Q90H | Missense Mutation (SNP) | VAF 10/258 reads (4%) | SIFT tolerated (0.51); PolyPhen benign (0.03); called by muse, mutect2
- SULT2A1 | c.184del p.D62Mfs*17 | Frame Shift Del (DEL) | VAF 160/1035 reads (15%) | called by mutect2, pindel, varscan2
- TUBGCP6 | c.825_827dup p.V276dup | In Frame Ins (INS) | VAF 33/292 reads (11%) | called by mutect2, varscan2
- ZNF488 | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AC011455.2 | c.1065C>T p.N355= | Silent (SNP) | VAF 270/1479 reads (18%) | catalogued as COSV99671535; called by muse, mutect2, varscan2
- ARID5B | c.3243G>C p.L1081= | Silent (SNP) | VAF 19/117 reads (16%) | catalogued as COSV99690349; called by muse, mutect2, varscan2
- ATP2A2 | c.1687C>T p.L563= | Silent (SNP) | VAF 12/145 reads (8%) | catalogued as COSV100428868; called by muse, mutect2
- DCAF4 | c.411C>A p.L137= | Silent (SNP) | VAF 72/906 reads (8%) | catalogued as COSV100611163; called by muse, mutect2
- FABP3 | c.45G>A p.K15= | Silent (SNP) | VAF 36/270 reads (13%) | catalogued as COSV101038454; called by muse, mutect2, varscan2
- GREB1 | c.5440C>T p.L1814= | Silent (SNP) | VAF 30/109 reads (28%) | catalogued as COSV99302370; called by muse, mutect2, varscan2
- GRIK3 | c.2166C>T p.N722= | Silent (SNP) | VAF 20/360 reads (6%) | catalogued as rs373589381; called by muse, mutect2
- GYS1 | c.645C>T p.A215= | Silent (SNP) | VAF 40/286 reads (14%) | catalogued as rs371721154; called by muse, varscan2
- IGSF1 | c.2868C>T p.L956= | Silent (SNP) | VAF 65/662 reads (10%) | catalogued as rs751111728, COSV63836671; called by muse, mutect2
- IGSF22 | c.1845C>T p.H615= | Silent (SNP) | VAF 27/351 reads (8%) | catalogued as rs183645626, COSV60040502; called by muse, mutect2
- INTS1 | c.225C>A p.T75= | Silent (SNP) | VAF 4/105 reads (4%) | catalogued as COSV67180072; called by muse, mutect2
- KIAA0930 | c.732C>T p.R244= (on ENST00000336156 / NM_001009880.2; = p.R249= on NM_015264.2) | Silent (SNP) | VAF 10/204 reads (5%) | catalogued as COSV99326019; called by muse, mutect2
- MMP8 | c.1134C>T p.D378= | Silent (SNP) | VAF 65/509 reads (13%) | catalogued as rs201019213, COSV52631640; called by muse, mutect2, varscan2
- MRNIP | c.741A>T p.P247= | Silent (SNP) | VAF 34/169 reads (20%) | catalogued as COSV52972434; called by muse, mutect2
- NELFB | c.1113G>A p.Q371= | Silent (SNP) | VAF 18/136 reads (13%) | catalogued as COSV100547015; called by muse, varscan2
- OR2M5 | c.90G>T p.L30= | Silent (SNP) | VAF 101/851 reads (12%) | catalogued as COSV63545932; called by muse, mutect2, varscan2
- P2RX4 | c.930G>A p.T310= | Silent (SNP) | VAF 13/208 reads (6%) | catalogued as rs780934600, COSV61502205; called by muse, mutect2
- PADI6 | c.1404G>A p.P468= | Silent (SNP) | VAF 94/170 reads (55%) | catalogued as rs746361913, COSV61884016; called by muse, mutect2, varscan2
- PKHD1 | c.11241C>G p.V3747= | Silent (SNP) | VAF 80/1131 reads (7%) | catalogued as COSV100945237; called by muse, mutect2
- SCN2B | c.624C>A p.G208= | Silent (SNP) | VAF 62/1117 reads (6%) | catalogued as COSV99635932; called by muse, mutect2
- SLC12A4 | c.1476G>A p.R492= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV57926770; called by muse, mutect2, varscan2
- SLC37A2 | c.372C>A p.L124= | Silent (SNP) | VAF 17/439 reads (4%) | catalogued as COSV100017440; called by muse, mutect2
- SPTLC3 | c.36G>A p.G12= | Silent (SNP) | VAF 28/269 reads (10%) | catalogued as COSV65464828; called by muse, mutect2, varscan2
- TLN1 | c.3669C>A p.L1223= | Silent (SNP) | VAF 60/623 reads (10%) | catalogued as COSV100148174; called by muse, mutect2
- TMEM11 | c.561C>T p.Y187= | Silent (SNP) | VAF 105/624 reads (17%) | catalogued as COSV58313121; called by muse, mutect2, varscan2
- TRIM7 | c.954C>T p.T318= | Silent (SNP) | VAF 7/108 reads (6%) | catalogued as COSV99220463; called by muse, mutect2
- TSPAN12 | c.642G>A p.L214= | Silent (SNP) | VAF 30/195 reads (15%) | catalogued as COSV56078969; called by muse, mutect2, varscan2
- ZP4 | c.852C>T p.S284= | Silent (SNP) | VAF 9/184 reads (5%) | catalogued as COSV63910845; called by muse, mutect2
- AP4S1 | c.306+4223G>A | Intron (SNP) | VAF 22/116 reads (19%) | called by mutect2, varscan2
- KRT18P23 | chr22:44570542 G>T | 3'Flank (SNP) | VAF 8/137 reads (6%) | called by muse, mutect2
- MACF1 | c.15832-10707C>T | Intron (SNP) | VAF 20/129 reads (16%) | catalogued as COSV57112463; called by muse, mutect2, varscan2
- MACF1 | c.15832-8071T>A | Intron (SNP) | VAF 35/121 reads (29%) | catalogued as COSV99245143, COSV99246489; called by muse, varscan2
